Gene-level copy-number profile of tumor specimen TCGA-05-4245-01A from TCGA case TCGA-05-4245, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 81.2 years (29,647 days).
Specimen TCGA-05-4245-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ff4a4303-ed17-42ae-9367-3102ea405194.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-05-4245-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,728 have no estimate.
https://portal.gdc.cancer.gov/files/44b62c27-7ac4-451f-920d-31d3a5267788

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 548; copy number 1: 73; copy number 2: 4,035; copy number 3: 9,894; copy number 4: 7,406; copy number 5: 15,700; copy number 6: 8,865; copy number 7: 5,390; copy number 8: 4,437; copy number 9: 1,457; copy number 10: 326; copy number 11: 218; copy number 12: 428; copy number 13: 56; copy number 14: 4; copy number 15: 23; copy number 17: 1; copy number 70: 12; copy number 76: 10; copy number 92: 1; copy number 133: 2; copy number 151: 1; copy number 221: 1; copy number 222: 7.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:38,601,418–38,605,609, 1 gene: ABCD1P2.
- chr14:106,421,711–106,422,218, 1 gene (within-gene range 0–6): IGHV4-39.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–6): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–6): IGHV3-43.
- chr21:7,744,962–8,701,562, 29 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 764 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–24,885,461, 389 genes, copy number 11–14 (broad region; genes not listed).
- chr5:55,307,989–58,863,414, 65 genes, copy number 12 (broad region; genes not listed).
- chr6:66,710,242–78,606,036, 138 genes, copy number 11–14 (broad region; genes not listed).
- chr7:38,239,580–38,378,804, 23 genes, copy number 15 (within-gene range 9–15): TRGC2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1.
- chr8:126,556,323–127,419,050, 1 gene, copy number 151 (within-gene range 9–222): PCAT1.
- chr8:126,766,196–129,844,504, 33 genes, copy number 70–222 (within-gene range 9–222): AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, MTRF1LP2, GSDMC, AC022973.5.
- chr14:22,123,318–22,497,718, 53 genes, copy number 13: TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41.
- chr14:22,547,506–22,552,156, 1 gene, copy number 13: TRAC.
- chr15:22,125,511–22,178,542, 5 genes, copy number 11–17 (within-gene range 7–17): OR4N3P, AC010760.1, RPS8P10, IGHV1OR15-1, IGHV1OR15-3.
- chr15:34,382,069–34,394,931, 2 genes, copy number 12 (within-gene range 12–23): MIR1233-1, AC025678.1.
- chr18:21,529,284–23,956,222, 54 genes, copy number 11: ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77.

Autosomal genes at a single copy (total copy number 1): 73. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
